Gene-level copy-number profile of tumor specimen HCM-BROD-0003-C71-01A from HCMI case HCM-BROD-0003-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 82.1 years (29,995 days).
Specimen HCM-BROD-0003-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bff6906f-fc37-4711-b9d8-3ee306c12afe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0003-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/933f20cb-32dd-497a-9bc2-068cd632f822

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 38; copy number 1: 101; copy number 2: 161; copy number 3: 13,051; copy number 4: 37,701; copy number 5: 5,669; copy number 6: 1,656; copy number 7: 22; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 38 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:50,437,028–50,974,634, 6 genes (within-gene range 0–4): FAF1, FAF1-AS1, RNU6-1026P, PHBP12, MRPS6P2, CDKN2C.
- chr6:148,272,304–148,552,048, 1 gene (within-gene range 0–3): SASH1.
- chr6:148,478,693–148,480,763, 1 gene: CYP51A1P3.
- chr9:21,966,929–22,128,103, 8 genes (within-gene range 0–3): CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.
- chr14:18,692,032–18,692,408, 1 gene: RPL22P20.
- chr17:18,511,221–18,551,705, 3 genes (within-gene range 0–4): FAM106A, USP32P2, SRP68P2.
- chr19:20,416,514–20,571,095, 3 genes (within-gene range 0–3): BNIP3P22, AC008554.1, BNIP3P23.
- chr19:52,012,765–52,095,765, 5 genes: ZNF614, ZNF432, AC011468.5, AC011468.1, ZNF841.
- chr22:28,772,674–29,057,488, 8 genes (within-gene range 0–3): CCDC117, XBP1, Z93930.2, Z93930.3, Z93930.1, ZNRF3, ZNRF3-IT1, ZNRF3-AS1.
- chr22:40,824,535–40,856,639, 1 gene: ST13.
- chr22:40,859,549–40,862,113, 1 gene (within-gene range 0–3): DNAJB7.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 101. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
